Somatic mutation profile of tumor specimen TCGA-12-0826-01A (aliquot TCGA-12-0826-01A-01W-0424-08) from TCGA case TCGA-12-0826, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 38.0 years (13,887 days).
Specimen TCGA-12-0826-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fca099d8-460e-481a-87dd-5c01036ac7be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0826-10A (Blood Derived Normal), aliquot TCGA-12-0826-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcbb3ad7-7f0f-4b89-bbbf-b7ab6ae0243a

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 4, Frame Shift Ins 2, 3'UTR 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP2 | c.1514G>A p.R505Q (on ENST00000547588 / NM_001122772.2; = p.R169Q on NM_014770.4) | Missense Mutation (SNP) | VAF 156/3051 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as rs747185110, COSV57726857, COSV99222619; called by muse, mutect2
- ASIC5 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1325989631, COSV101539722; called by muse, mutect2
- ATP8A2 | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 200/593 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs150714658; called by muse, mutect2
- CABP1 | c.985G>C p.E329Q (on ENST00000316803 / NM_001033677.1; = p.E126Q on NM_004276.5) | Missense Mutation (SNP) | VAF 3621/4082 reads (89%) | SIFT tolerated (0.34); PolyPhen benign (0.081); catalogued as COSV99974589; called by muse, varscan2
- CACNA1A | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64194248; called by muse, mutect2
- CACNA1F | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.333); catalogued as rs782649560, COSV100544553; called by muse, mutect2, varscan2
- CFAP94 | c.596G>T p.S199I (on ENST00000320267 / NM_001352064.2; = p.S205I on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100209110; called by muse, mutect2, varscan2
- DNAH11 | c.10244C>T p.A3415V | Missense Mutation (SNP) | VAF 208/1283 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs778003957, COSV100178246; called by muse, mutect2, varscan2
- DNAJC14 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs61758445, COSV54477721, COSV54479201; called by muse, mutect2, varscan2
- DPH6 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 40/423 reads (9%) | catalogued as rs371901885; called by muse, mutect2
- ERCC6L | c.3217A>T p.R1073W | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100559054; called by muse, mutect2, varscan2
- ERGIC2 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as rs1248092386, COSV100791951, COSV64112763; called by muse, mutect2, varscan2
- FAM91A1 | c.213C>A p.S71R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100593494; called by muse, mutect2
- FANCM | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 122/379 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99950747; called by muse, mutect2, varscan2
- FARS2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 24/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99212937; called by muse, mutect2
- GALNT17 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 58/1530 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1292542852, COSV100352861, COSV61160299; called by muse, mutect2
- HMCN1 | c.1957G>A p.V653M | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs754249769, COSV54913016; called by muse, mutect2
- IL17RE | c.1209dup p.V404Rfs*107 | Frame Shift Ins (INS) | VAF 7/44 reads (16%) | catalogued as rs748230310; called by mutect2, pindel
- INTS6L | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100878051; called by muse, mutect2
- JAK3 | c.2444C>T p.T815M | Missense Mutation (SNP) | VAF 40/650 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs200579386, COSV101512898, COSV99070387; called by muse, mutect2
- KDM7A | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 63/384 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs756878349, COSV50089983; called by muse, mutect2, varscan2
- KRT73 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs146681578; called by muse, mutect2, varscan2
- NOMO3 | c.873+1G>A p.X291_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99530743; called by mutect2, varscan2
- OR10A2 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV100224992; called by muse, mutect2
- OR2D2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113111396, COSV55056460, COSV55057158; called by muse, mutect2, varscan2
- PGBD4 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 29/198 reads (15%) | catalogued as rs1474853461, COSV99854665; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.376); catalogued as COSV99461041; called by muse, mutect2, varscan2
- PTPRK | c.3829G>A p.D1277N (on ENST00000368215 / NM_001291984.2; = p.D1278N on NM_002844.4) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.884); catalogued as rs755526385, COSV100950599, COSV63907987; called by muse, mutect2, varscan2
- RBM28 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 182/600 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV99775574; called by muse, mutect2, varscan2
- RCBTB2 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100749571; called by muse, mutect2
- SEMG1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs201334489; called by muse, mutect2, varscan2
- SEPTIN12 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 83/369 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99190505; called by muse, varscan2
- STK35 | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 49/825 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.246); catalogued as COSV99852678; called by muse, mutect2
- TASOR | c.1843C>T p.P615S (on ENST00000355628 / NM_001365636.2; = p.P219S on NM_015224.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV100843428; called by muse, mutect2, varscan2
- TOP3B | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100592415; called by muse, mutect2, varscan2
- TTBK1 | c.1316dup p.D440Rfs*19 | Frame Shift Ins (INS) | VAF 10/63 reads (16%) | catalogued as rs757606010; called by mutect2, varscan2
- USH2A | c.11599C>T p.P3867S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231764; called by muse, mutect2, varscan2
- DISP1 | c.4392del p.F1464Lfs*4 | Frame Shift Del (DEL) | VAF 22/186 reads (12%) | called by mutect2, pindel, varscan2
- DRD5 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NOL6 | c.3222_3223delinsA p.Y1074* | Nonsense Mutation (DEL) | VAF 3/20 reads (15%) | called by muse*, pindel
- TPTE | c.1388T>A p.L463* (on ENST00000618007 / NM_199261.4; = p.L445* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 75/439 reads (17%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.27G>A p.L9= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV99327476; called by muse, mutect2, varscan2
- BCHE | c.171T>C p.L57= | Silent (SNP) | VAF 103/253 reads (41%) | catalogued as COSV100012294; called by muse, mutect2, varscan2
- CACNA1G | c.1803G>A p.T601= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs751292455, COSV61732727; called by muse, mutect2, varscan2
- EPX | c.750C>T p.G250= | Silent (SNP) | VAF 45/316 reads (14%) | catalogued as rs943769778, COSV56596111; called by muse, mutect2, varscan2
- HECW1 | c.2058G>A p.S686= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as rs775565051, COSV67826461; called by muse, mutect2, varscan2
- IL36A | c.384C>T p.I128= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as rs555854077, COSV99382084; called by muse, mutect2
- JCAD | c.2196G>A p.T732= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs1281929200, COSV64760571; called by muse, mutect2, varscan2
- KCNQ1 | c.672G>A p.T224= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs550887954, COSV50100072, COSV50123503; ClinVar: likely benign; called by muse, mutect2
- MYO1F | c.3156C>T p.Y1052= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1370300693, COSV100596482; called by muse, mutect2, varscan2
- TTC22 | c.1002G>A p.A334= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs199739536, COSV64881095; called by muse, mutect2
- HAO2 | c.*1G>T | 3'UTR (SNP) | VAF 230/1006 reads (23%) | catalogued as COSV100377883, COSV100378069; called by mutect2, varscan2
